Somatic mutation profile of tumor specimen TCGA-PK-A5H9-01A (aliquot TCGA-PK-A5H9-01A-11D-A29I-10) from TCGA case TCGA-PK-A5H9, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 27.9 years (10,173 days).
Specimen TCGA-PK-A5H9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31fef0f9-7af5-4c27-9393-6e5b5ca2998b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PK-A5H9-10A (Blood Derived Normal), aliquot TCGA-PK-A5H9-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47f92cce-31c6-42a7-8c47-6525ba79f8a0

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.5537C>A p.T1846N | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.715); catalogued as rs1437572634; called by muse, mutect2, varscan2
- PCDHA2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65366617; called by muse, mutect2
- RRNAD1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs1403625950; called by muse, mutect2, varscan2
- TFDP3 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745953075, COSV59536346, COSV59536950; called by muse, mutect2, varscan2
- ARHGEF18 | c.407C>A p.A136D (on ENST00000359920 / NM_001130955.2; = p.A32D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHRDL2 | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- FUCA1 | c.716A>C p.Y239S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KDM6B | c.3062T>G p.L1021R | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- LHFPL4 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- SAXO1 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- HEATR5A | c.5598T>C p.T1866= | Silent (SNP) | VAF 20/73 reads (27%) | called by muse, varscan2
- PLCB4 | c.3384G>A p.K1128= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as rs1460273021, COSV53810421; called by muse, mutect2
- TICAM1 | c.69C>T p.L23= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99941334; called by muse, mutect2, varscan2
- TTC39C | c.1290G>A p.V430= (on ENST00000317571 / NM_001135993.2; = p.V369= on NM_153211.4) | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
